TCGA case TCGA-02-0104 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/db38e6b7-102f-4670-875f-b327790c70e4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 29 years; Vital status: Dead; Days to death: 1,977 days (5.4 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 29.3 years (10,699 days); Year of diagnosis: 2001; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 1,536 days (4.2 years); Days to treatment end: 1,581 days (4.3 years); Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 1,536 days (4.2 years); Days to treatment end: 1,786 days (4.9 years); Number of cycles: 9; Treatment dose: 200 mg/m2/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 1,536 days (4.2 years); Days to treatment end: 1,786 days (4.9 years); Number of cycles: 9; Treatment dose: 75 mg/m2; Route of administration: Oral.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 33.3 years (12,156 days); Days to diagnosis: 1,457 days (4.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 1,457 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 1,457 days (4.0 years).
- Days to follow up: 1,977 days (5.4 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.
- Karnofsky performance status: 80.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-02-0104-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.1; Intermediate dimension: 1; Shortest dimension: 0.1.
  Slide TCGA-02-0104-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
  Slide TCGA-02-0104-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
- Sample TCGA-02-0104-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,977 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,977 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,457 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-02-0104-01): tumor purity 0.88, ploidy 1.95, whole-genome doublings 0 (call status: legacy_call).
